Somatic mutation profile of tumor specimen MMRF_2631_1_BM_CD138pos (aliquot MMRF_2631_1_BM_CD138pos_T1_KHS5U_L13304) from MMRF case MMRF_2631, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.8 years (23,294 days).
Specimen MMRF_2631_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac2a0839-239f-4d4d-945c-e37e3e0f2a6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2631_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2631_1_PB_WBC_C3_KHS5U_L13305; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04fb46e3-c4ed-43ea-9ff8-b6cfd92711ea

The open-access MAF lists 80 somatic variants for this specimen: 31 protein-altering or splice-affecting, 14 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 21, Silent 14, Intron 8, 5'UTR 3, 3'Flank 2, Frame Shift Del 2, Nonsense Mutation 1, RNA 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 40/579 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ACAN | c.2621G>C p.G874A | Missense Mutation (SNP) | VAF 8/212 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs945279211; called by muse, mutect2
- CLPTM1 | c.186-2A>G p.X62_splice | Splice Site (SNP) | VAF 90/217 reads (41%) | catalogued as rs1195335160, COSV100493786, COSV61611538; called by muse, mutect2, varscan2
- CRMP1 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61480182; called by muse, mutect2, varscan2
- FBXW5 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs1442612546; called by muse, mutect2
- GLI2 | c.3011G>A p.R1004H (on ENST00000361492 / NM_001374353.1; = p.R1021H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs749819734, COSV58053376; called by muse, mutect2, varscan2
- GMPR | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162015376; called by muse, mutect2, varscan2
- ICE1 | c.6131C>T p.S2044L | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs753410823; called by muse, mutect2
- MED14 | c.4061C>T p.T1354M | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as COSV100247377; called by muse, mutect2, varscan2
- MMP16 | c.1450C>T p.P484S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54170614; called by muse, mutect2, varscan2
- MYO7B | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 10/264 reads (4%) | catalogued as rs919517000; called by muse, mutect2
- NAV3 | c.3107G>T p.R1036I | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57061286, COSV57105503; called by muse, mutect2, varscan2
- RUNX1T1 | c.1471G>A p.A491T (on ENST00000265814 / NM_001198628.1; = p.A464T on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.838); catalogued as rs756883632, COSV56146029; called by muse, mutect2, varscan2
- TBC1D8B | c.98G>A p.G33D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1406112485; called by muse, mutect2
- TCF7L1 | c.241G>T p.D81Y | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV56401564; called by muse, mutect2, varscan2
- TIMD4 | c.248A>T p.K83I | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs867149071; called by muse, mutect2
- TMX2 | c.722C>G p.A241G | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53556697; called by muse, mutect2
- CSRNP3 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2
- DDI2 | c.611C>G p.A204G | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); called by muse, mutect2
- DOCK4 | c.1796G>T p.G599V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.162); called by mutect2, varscan2
- DXO | c.832T>G p.W278G | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ECEL1 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GNAZ | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.289); called by muse, mutect2
- IGHV2-70D | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- IGLV4-60 | c.208_223del p.K70Efs*? | Frame Shift Del (DEL) | VAF 46/170 reads (27%) | called by pindel, varscan2
- MED13L | c.3745A>G p.N1249D | Missense Mutation (SNP) | VAF 19/309 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.003); called by muse, mutect2
- PBX4 | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSPC1 | c.95_102del p.A32Gfs*97 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel
- SLC26A7 | c.1604A>C p.Q535P | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- SLC27A5 | c.1765+6G>T | Splice Region (SNP) | VAF 18/468 reads (4%) | called by muse, mutect2
- SLC2A4 | c.634C>G p.P212A | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ADPRH | c.1071T>C p.L357= | Silent (SNP) | VAF 30/303 reads (10%) | called by muse, varscan2
- ATXN1 | c.847C>T p.L283= | Silent (SNP) | VAF 24/151 reads (16%) | called by muse, mutect2, varscan2
- C4orf46 | c.126G>A p.P42= | Silent (SNP) | VAF 23/70 reads (33%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.3606C>T p.H1202= | Silent (SNP) | VAF 6/113 reads (5%) | catalogued as rs771490764; called by muse, mutect2
- CRYBA2 | c.138C>T p.R46= | Silent (SNP) | VAF 26/215 reads (12%) | called by muse, varscan2
- DNAH7 | c.1293C>T p.D431= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs370258473; called by muse, mutect2, varscan2
- F3 | c.498C>G p.V166= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as rs1490657838; called by muse, mutect2
- IGHJ3 | c.21C>T p.G7= | Silent (SNP) | VAF 31/35 reads (89%) | catalogued as rs782011349; called by muse, mutect2, varscan2
- MAPKAP1 | c.1383C>T p.H461= (on ENST00000265960 / NM_001006617.3; = p.H425= on NM_024117.3) | Silent (SNP) | VAF 19/244 reads (8%) | catalogued as rs144621305; called by muse, mutect2
- PDE8B | c.1272A>T p.S424= | Silent (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2, varscan2
- PLPPR5 | c.360C>T p.V120= | Silent (SNP) | VAF 14/234 reads (6%) | called by muse, mutect2
- RINL | c.1509G>A p.L503= (on ENST00000591812 / NM_001195833.2; = p.L389= on NM_198445.4) | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- XBP1 | c.483T>C p.S161= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- ZNF44 | c.291C>T p.N97= (on ENST00000356109 / NM_001164276.2; = p.N49= on NM_016264.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV61136024; called by muse, mutect2, varscan2
- BCL2 | c.*4045A>G | 3'UTR (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- BCL9L | c.*1464G>A | 3'UTR (SNP) | VAF 13/165 reads (8%) | called by muse, mutect2
- C20orf194 | c.*158C>T | 3'UTR (SNP) | VAF 21/147 reads (14%) | catalogued as rs529163309; called by muse, mutect2, varscan2
- CHML | c.-197A>C | 5'UTR (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- CIT | c.*146C>T | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- COLCA1 | n.5498A>C | RNA (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
- COMMD9 | chr11:36271656 C>A | 3'Flank (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- CYTH2 | c.353+62C>T | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- DENND3 | c.-146C>G | 5'UTR (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- EFCAB2 | c.*2320G>A | 3'UTR (SNP) | VAF 15/141 reads (11%) | called by muse, mutect2, varscan2
- GRM7 | c.-167G>A | 5'UTR (SNP) | VAF 7/45 reads (16%) | catalogued as rs1024823699; called by muse, mutect2, varscan2
- LSG1 | c.*508C>G | 3'UTR (SNP) | VAF 18/164 reads (11%) | called by muse, mutect2, varscan2
- MAPK14 | c.682+64C>G | Intron (SNP) | VAF 9/113 reads (8%) | called by muse, mutect2
- MBL2 | c.*2367C>T | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- MBP | c.576+1205G>C | Intron (SNP) | VAF 16/97 reads (16%) | called by muse, mutect2, varscan2
- MCOLN2 | c.*853T>C | 3'UTR (SNP) | VAF 5/73 reads (7%) | called by muse, mutect2
- MIDEAS | c.2725-20C>G | Intron (SNP) | VAF 11/151 reads (7%) | called by muse, mutect2
- NDST2 | c.*90G>A | 3'UTR (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- NECTIN1 | c.*782G>A | 3'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- NOS1 | c.*6837G>A | 3'UTR (SNP) | VAF 9/64 reads (14%) | catalogued as rs774790706; called by muse, mutect2, varscan2
- PDCD5 | c.330+153G>C | Intron (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- PDX1 | c.*133A>T | 3'UTR (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- PER2 | c.*1972G>A | 3'UTR (SNP) | VAF 12/72 reads (17%) | called by muse, mutect2, varscan2
- PPM1F | c.*102G>A | 3'UTR (SNP) | VAF 9/56 reads (16%) | catalogued as rs915487722, COSV99601300; called by mutect2, varscan2
- RGS20 | c.510+1333G>A | Intron (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- RGS20 | c.510+1334C>A | Intron (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- RTF1 | c.*1549G>A | 3'UTR (SNP) | VAF 7/39 reads (18%) | called by muse, mutect2, varscan2
- SFXN5 | c.*67C>A | 3'UTR (SNP) | VAF 22/56 reads (39%) | called by muse, mutect2, varscan2
- SLC26A4 | c.*2059G>T | 3'UTR (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143625040 T>A | 3'Flank (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- SUDS3 | c.*2661C>A | 3'UTR (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- TMEM129 | c.*352C>T | 3'UTR (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2, varscan2
- XKR6 | c.764+91547T>G | Intron (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- ZNF33B | c.*1966A>G | 3'UTR (SNP) | VAF 17/152 reads (11%) | called by muse, mutect2, varscan2
- ZNF496 | c.*2683G>T | 3'UTR (SNP) | VAF 47/94 reads (50%) | called by muse, mutect2, varscan2
